Gene-level copy-number profile of tumor specimen TCGA-VQ-A922-01A from TCGA case TCGA-VQ-A922, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 70.4 years (25,700 days).
Specimen TCGA-VQ-A922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.0b0805bb-edaa-400f-ae9f-effed3dbb605.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A922-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/18fb7029-91bb-4566-bc2c-82e00efb33cf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 488; copy number 2: 3,559; copy number 3: 13,490; copy number 4: 12,936; copy number 5: 11,676; copy number 6: 5,823; copy number 7: 4,632; copy number 8: 2,431; copy number 9: 1,611; copy number 10: 1,035; copy number 11: 717; copy number 12: 196; copy number 13: 412; copy number 14: 66; copy number 15: 122; copy number 16: 188; copy number 17: 48; copy number 18: 7; copy number 20: 39; copy number 21: 15; copy number 23: 14; copy number 24: 36; copy number 25: 36; copy number 26: 60; copy number 27: 28; copy number 29: 28; copy number 30: 27; copy number 32: 23; copy number 46: 13; copy number 52: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A922-01A-11D-A40Z-01): tumor purity 0.35, ploidy 5.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,969,038–60,522,120, 1 gene (within-gene range 0–1): PDE4D.
- chr5:59,703,606–60,844,274, 14 genes: MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7.
- chr9:3,218,297–3,691,814, 4 genes (within-gene range 0–1): RFX3, AL354941.1, RFX3-AS1, AL354977.2.
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.
- chr14:67,819,779–68,730,218, 7 genes (within-gene range 0–6): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr14:103,041,469–103,149,408, 9 genes: RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,710 genes in 90 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:244,352,635–246,507,312, 32 genes, copy number 9 (within-gene range 2–9): C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8, AC104462.2, AC104462.1, SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P.
- chr2:42,826,322–44,320,310, 32 genes, copy number 9–13 (within-gene range 8–13): CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1, RN7SKP66, DYNC2LI1, ABCG5, ABCG8, LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19.
- chr3:91,356,755–97,752,460, 30 genes, copy number 12–23 (within-gene range 7–23): ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:101,648,889–107,240,671, 34 genes, copy number 10 (within-gene range 6–10): ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1, ZPLD1, AC063938.1, RNU6-461P, RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1, ALCAM, CBLB, AC131237.1, AC079382.1, AC079382.2, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3.
- chr3:108,589,705–115,147,288, 115 genes, copy number 9–27 (within-gene range 5–27) (broad region; genes not listed).
- chr3:163,026,396–188,890,671, 425 genes, copy number 9–18 (within-gene range 8–18) (broad region; genes not listed).
- chr3:191,199,241–198,222,513, 194 genes, copy number 9–13 (broad region; genes not listed).
- chr4:51,843,000–54,295,272, 38 genes, copy number 11–15 (within-gene range 5–21): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3.
- chr4:183,639,635–186,500,997, 75 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr5:58,198–1,728,172, 65 genes, copy number 9 (broad region; genes not listed).
- chr5:15,384,220–17,486,829, 37 genes, copy number 9–11: MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218.
- chr5:35,617,844–51,964,445, 195 genes, copy number 9–16 (broad region; genes not listed).
- chr6:17,953,572–23,649,774, 60 genes, copy number 9–18 (within-gene range 6–18): AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1.
- chr6:30,485,940–30,900,156, 31 genes, copy number 16 (within-gene range 7–16): RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1.
- chr6:41,598,723–45,377,953, 128 genes, copy number 10–26 (within-gene range 4–26) (broad region; genes not listed).
- chr6:71,028,582–74,734,319, 65 genes, copy number 10–12 (broad region; genes not listed).
- chr6:132,518,830–145,964,423, 229 genes, copy number 9–14 (broad region; genes not listed).
- chr7:104,126,341–106,126,700, 31 genes, copy number 20–23 (within-gene range 5–25): ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1.
- chr8:66,176,376–80,080,775, 204 genes, copy number 9–13 (within-gene range 8–13) (broad region; genes not listed).
- chr8:99,340,305–101,452,452, 61 genes, copy number 12–30 (broad region; genes not listed).
- chr8:119,325,171–133,302,022, 209 genes, copy number 9–17 (within-gene range 8–17) (broad region; genes not listed).
- chr8:139,096,305–143,738,234, 122 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr10:32,173,684–38,783,108, 120 genes, copy number 13–20 (broad region; genes not listed).
- chr11:41,122,907–44,251,962, 46 genes, copy number 9 (within-gene range 6–9): RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740, AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2.
- chr11:55,811,367–56,543,281, 64 genes, copy number 10 (broad region; genes not listed).
- chr12:46,970,504–48,852,842, 92 genes, copy number 10 (broad region; genes not listed).
- chr12:68,686,951–70,637,440, 45 genes, copy number 12–25 (within-gene range 7–25): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr13:110,523,066–113,658,198, 71 genes, copy number 9–13 (broad region; genes not listed).
- chr14:21,563,819–22,190,713, 60 genes, copy number 9: RBBP4P5, OR10G3, AC243972.2, OR10G1P, UBE2NP1, TRAV1-1, OR10G2, TRAV1-2, ARL6IP1P1, OR4E2, OR4E1, AC243972.3, TRAV2, AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:49,552,633–50,231,578, 38 genes, copy number 10–16 (within-gene range 4–16): RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2.
- chr15:89,518,523–101,933,350, 306 genes, copy number 11–15 (within-gene range 8–15) (broad region; genes not listed).
- chr17:3,977,103–4,898,061, 42 genes, copy number 11 (within-gene range 5–11): LINC01975, ZZEF1, RNA5SP434, CYB5D2, ANKFY1, AC087292.1, Y_RNA, RYKP1, AC087742.1, UBE2G1, MFSD1P1, RN7SL774P, SPNS3, AC127521.1, AC118754.1, SPNS2, MYBBP1A, GGT6, AC118754.2, TXNP4, SMTNL2, LINC01996, RNU6-955P, ALOX15, PELP1, AC091153.2, AC091153.3, AC091153.1, ARRB2, MED11, AC091153.4, CXCL16, ZMYND15, TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2, MINK1, ATP6V0CP1.
- chr17:34,255,218–44,752,264, 559 genes, copy number 9–16 (broad region; genes not listed).
- chr17:58,345,206–60,018,975, 60 genes, copy number 12–29 (within-gene range 6–29): AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4, TEX14, U3, IGBP1P2, RNU1-108P, AC011195.1, RNU1-52P, RNVU1-34, RAD51C, AC025521.1, PPM1E, Metazoa_SRP, RNU6-518P, AC100832.1, Metazoa_SRP, AC100832.2, TRIM37, RN7SL716P, AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17, YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1.
- chr17:76,453,351–76,841,099, 32 genes, copy number 10 (within-gene range 8–10): AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, AC015802.7, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4, JMJD6, AC005837.3, METTL23, AC005837.2, SRSF2, MFSD11, MIR636, RNU6-97P, LINC02080, AC016168.4.
- chr19:27,638,483–29,841,818, 52 genes, copy number 24–32: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2.
- chr19:41,373,971–41,930,150, 38 genes, copy number 11: AC011462.4, EXOSC5, BCKDHA, AC011462.3, AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A, ARHGEF1, ERFL.
- chr20:16,576,068–18,095,632, 35 genes, copy number 9–11: AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P.
- chr20:34,689,097–37,872,129, 102 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr21:36,966,461–39,062,894, 44 genes, copy number 9: AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2.

Autosomal genes at a single copy (total copy number 1): 442. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
